Somatic mutation profile of tumor specimen 0DIPLB from CCDI case PBBVPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 10.9 years (3,980 days).
Specimen 0DIPLB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 620e02e7-909f-430a-b552-43e167ab2e98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/241b5b5b-d93d-48a7-914f-11fb8d79a04c

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAX5 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 69/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751431527, COSV63907177; called by muse, varscan2
- STOX1 | c.2372C>G p.S791C | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV53815398; called by muse, mutect2, varscan2
- OR2AK2 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 22/828 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- CSMD1 | c.540C>T p.H180= | Silent (SNP) | VAF 145/654 reads (22%) | catalogued as rs368684088; called by muse, mutect2, varscan2
- CSNK1G1 | c.-56A>T | 5'UTR (SNP) | VAF 12/72 reads (17%) | catalogued as rs1015609495; called by muse, mutect2, varscan2
- DDX20 | c.566-17T>A | Intron (SNP) | VAF 34/178 reads (19%) | called by mutect2, varscan2
